Somatic mutation profile of tumor specimen TCGA-AA-A03J-01A (aliquot TCGA-AA-A03J-01A-21W-A096-10) from TCGA case TCGA-AA-A03J, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage I; Age at diagnosis: 65.7 years (23,986 days).
Specimen TCGA-AA-A03J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6cb0f4c0-6ac4-43e5-b792-3277b8c5916c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A03J-11A (Solid Tissue Normal), aliquot TCGA-AA-A03J-11A-11W-A096-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5fbde2a-0720-4cbc-8c8e-12cffc26f756

The open-access MAF lists 102 somatic variants for this specimen: 70 protein-altering or splice-affecting, 27 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 27, Splice Site 4, Splice Region 4, Nonsense Mutation 4, Intron 3, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 43/118 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 12/109 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.396G>C p.K132N | Missense Mutation (SNP) | VAF 59/147 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866775781, COSV52688381, COSV52705927, COSV52891203, COSV53339296; ClinVar: conflicting interpretations of pathogenicity / likely pathogenic; called by muse, mutect2, varscan2
- ABI1 | c.209A>G p.N70S | Missense Mutation (SNP) | VAF 198/650 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.049); catalogued as rs775422208, COSV61018200; called by muse, mutect2, varscan2
- ACTN3 | c.1214G>A p.R405Q | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.14); PolyPhen benign (0.056); catalogued as rs555878172, COSV101557798; called by muse, mutect2, varscan2
- APC | c.730-1G>A p.X244_splice | Splice Site (SNP) | VAF 66/256 reads (26%) | catalogued as CS941417, COSV57335072; called by muse, mutect2, varscan2
- ASIC2 | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 107/732 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765631881, COSV56758247; called by muse, mutect2, varscan2
- AVPR2 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.501); catalogued as rs781891175, COSV61686481; called by muse, mutect2, varscan2
- BTAF1 | c.437G>A p.R146Q | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.223); catalogued as rs753952218, COSV99794759; called by muse, mutect2, varscan2
- CA13 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs767404207, COSV58797897; called by muse, mutect2
- CFAP58 | c.288G>T p.K96N | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.929); catalogued as COSV57211844; called by muse, mutect2, varscan2
- CHRDL1 | c.1266G>T p.Q422H (on ENST00000372045; = p.Q428H on NM_145234.4) | Missense Mutation (SNP) | VAF 82/618 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV54326468; called by muse, mutect2, varscan2
- CLIP4 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 158/485 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.939); catalogued as rs747478205, COSV60747761; called by muse, mutect2, varscan2
- CNGA2 | c.625A>T p.K209* | Nonsense Mutation (SNP) | VAF 26/204 reads (13%) | catalogued as COSV61703651; called by muse, mutect2, varscan2
- CNTN6 | c.2483G>T p.W828L | Missense Mutation (SNP) | VAF 32/256 reads (13%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.996); catalogued as COSV100609840, COSV63168477; called by muse, mutect2, varscan2
- CRACD | c.2831C>T p.P944L | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as rs1291106985, COSV99948396; called by muse, mutect2, varscan2
- DNAJC13 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as rs1180074742, COSV53453428; called by muse, mutect2, varscan2
- DOK5 | c.177T>C p.V59= | Splice Region (SNP) | VAF 72/853 reads (8%) | catalogued as COSV99373108; called by muse, mutect2
- DPP8 | c.2177A>C p.E726A (on ENST00000341861 / NM_001320875.2; = p.E710A on NM_130434.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/166 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100202020; called by muse, mutect2, varscan2
- ECHDC1 | c.64A>G p.K22E (on ENST00000531967 / NM_001139510.1; = p.K16E on NM_018479.3) | Missense Mutation (SNP) | VAF 55/162 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.058); catalogued as COSV58932968; called by muse, mutect2, varscan2
- EDIL3 | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 40/370 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56905805; called by muse, mutect2, varscan2
- EYA1 | c.743C>T p.T248M | Missense Mutation (SNP) | VAF 177/968 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); catalogued as rs186736708; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAM166C | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs182908309; called by muse, mutect2, varscan2
- FLNA | c.4062C>G p.D1354E | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV100774231; called by muse, mutect2
- GABRR3 | c.1232C>T p.S411L | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.046); catalogued as rs376960773; called by muse, mutect2, varscan2
- GCNT2 | c.694G>A p.V232I | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.059); catalogued as rs773968312, COSV65457708; called by muse, mutect2, varscan2
- GDAP1 | c.572G>A p.R191Q | Missense Mutation (SNP) | VAF 119/319 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.183); catalogued as rs772722746, COSV55185226; called by muse, mutect2, varscan2
- GSTM5 | c.31C>T p.R11C | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV56658295; called by muse, mutect2, varscan2
- HAO1 | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs746154151, COSV66494573; called by muse, mutect2, varscan2
- HJV | c.182C>A p.A61E | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.038); catalogued as COSV100382171; called by muse, varscan2
- HMGB3 | c.151-1G>A p.X51_splice | Splice Site (SNP) | VAF 24/83 reads (29%) | catalogued as COSV57486599, COSV57486871; called by muse, mutect2, varscan2
- KIF11 | c.766G>A p.V256I | Missense Mutation (SNP) | VAF 53/311 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV99585578; called by muse, mutect2, varscan2
- LMX1A | c.437G>T p.G146V | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV54223482; called by muse, mutect2, varscan2
- MAGEE1 | c.1138G>A p.V380M | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs782669089, COSV63910576; called by muse, mutect2, varscan2
- MANBA | c.333C>A p.F111L | Missense Mutation (SNP) | VAF 57/416 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99898196; called by muse, mutect2, varscan2
- MAP7D3 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 62/252 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764183267, COSV60171631; called by muse, varscan2
- MYH11 | c.721C>T p.R241* | Nonsense Mutation (SNP) | VAF 65/412 reads (16%) | catalogued as rs112895882, COSV100257432; called by muse, mutect2, varscan2
- MYH4 | c.3919C>T p.R1307* | Nonsense Mutation (SNP) | VAF 42/224 reads (19%) | catalogued as rs151253822, COSV99701952; called by muse, mutect2, varscan2
- NDUFS6 | c.325A>G p.T109A | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.047); catalogued as COSV56877253; called by muse, mutect2, varscan2
- OR10P1 | c.820G>A p.V274I | Missense Mutation (SNP) | VAF 42/119 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as rs772594253, COSV59007644; called by muse, mutect2, varscan2
- OR2T33 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as COSV58815643; called by muse, mutect2, varscan2
- OR2T8 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs1204867691, COSV60663374; called by muse, mutect2, varscan2
- OR6C6 | c.364G>A p.V122I | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.009); catalogued as rs201844969; called by muse, mutect2, varscan2
- OTOL1 | c.1291G>A p.V431I | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs370829105; called by muse, mutect2, varscan2
- P2RY14 | c.451C>A p.L151I | Missense Mutation (SNP) | VAF 77/478 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.023); catalogued as COSV56385000; called by muse, mutect2, varscan2
- PCDH17 | c.70T>C p.S24P | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100931376; called by muse, mutect2, varscan2
- PCDHGA2 | c.604C>A p.R202S | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs377473177, COSV53977480; called by muse, mutect2, varscan2
- PGK1 | c.1215T>G p.G405= | Splice Region (SNP) | VAF 357/1270 reads (28%) | catalogued as COSV59371597; called by muse, mutect2, varscan2
- POLR3A | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 56/236 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1262335730, COSV100965512; called by muse, mutect2, varscan2
- PROK2 | c.317C>T p.T106I (on ENST00000295619 / NM_001126128.2; = p.T85I on NM_021935.4) | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV55209118; called by muse, mutect2, varscan2
- PSG1 | c.430+1G>A p.X144_splice | Splice Site (SNP) | VAF 50/288 reads (17%) | catalogued as rs375340094; called by muse, mutect2, varscan2
- PXDN | c.1985G>A p.R662Q | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); catalogued as rs776973469, COSV53231432, COSV53248644; called by muse, mutect2, varscan2
- RADX | c.1955C>T p.P652L | Missense Mutation (SNP) | VAF 43/364 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs759731966, COSV65319199; called by muse, mutect2, varscan2
- RBMS3 | c.359C>A p.A120E | Missense Mutation (SNP) | VAF 80/456 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV56153301; called by muse, mutect2, varscan2
- REST | c.3010G>A p.E1004K | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV58361540; called by muse, mutect2, varscan2
- RIMBP2 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs200895310, COSV99898041; called by muse, mutect2, varscan2
- SCAMP5 | c.139A>G p.N47D | Missense Mutation (SNP) | VAF 67/417 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as COSV62643647; called by muse, mutect2, varscan2
- SH3YL1 | c.402A>G p.G134= | Splice Region (SNP) | VAF 49/167 reads (29%) | catalogued as COSV62156770; called by muse, mutect2, varscan2
- SPTA1 | c.17A>G p.K6R | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); catalogued as COSV100934064; called by muse, mutect2, varscan2
- SUSD5 | c.384C>G p.Y128* | Nonsense Mutation (SNP) | VAF 62/245 reads (25%) | catalogued as rs368923559, COSV58877054; called by muse, varscan2
- TGFBR3 | c.1519A>G p.T507A | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV53027829; called by muse, mutect2, varscan2
- TRPM1 | c.3368G>A p.R1123H | Missense Mutation (SNP) | VAF 109/314 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.018); catalogued as rs200369359, COSV99855091; called by muse, mutect2, varscan2
- UHRF1BP1 | c.2454G>T p.M818I | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99511333; called by muse, mutect2, varscan2
- VPS13C | c.8935A>G p.I2979V (on ENST00000644861 / NM_020821.3; = p.I2936V on NM_017684.5) | Missense Mutation (SNP) | VAF 129/710 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as COSV99826595; called by muse, mutect2, varscan2
- WNT3 | c.892C>T p.R298W | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56644543; called by muse, mutect2, varscan2
- ZNF329 | c.1378T>C p.C460R | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100798654; called by muse, mutect2, varscan2
- ZNF425 | c.331G>C p.E111Q | Missense Mutation (SNP) | VAF 56/206 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.093); catalogued as COSV100955351, COSV65200798; called by muse, mutect2, varscan2
- ZNF646 | c.3355G>T p.G1119C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.243); catalogued as COSV99761958; called by muse, mutect2, varscan2
- F11R | c.694+2T>C p.X232_splice | Splice Site (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- PPFIBP1 | c.1042+8_1042+9insTA | Splice Region (INS) | VAF 32/256 reads (13%) | called by mutect2, varscan2
- BNC1 | c.1338G>A p.T446= | Silent (SNP) | VAF 26/176 reads (15%) | catalogued as rs376158536; called by muse, mutect2, varscan2
- BTBD9 | c.1809C>T p.N603= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as rs1470755749, COSV58426539, COSV58429993; called by muse, mutect2, varscan2
- CANT1 | c.1062C>T p.D354= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV56605984; called by muse, mutect2, varscan2
- CTNNA2 | c.708G>A p.T236= | Silent (SNP) | VAF 12/113 reads (11%) | catalogued as rs1372611257, COSV63580575; called by muse, mutect2, varscan2
- DLG3 | c.978C>T p.Y326= | Silent (SNP) | VAF 13/49 reads (27%) | catalogued as rs370555109, COSV52079971; called by muse, mutect2, varscan2
- EPB41L1 | c.1722G>C p.R574= | Silent (SNP) | VAF 16/91 reads (18%) | catalogued as COSV52439954; called by muse, mutect2, varscan2
- FGG | c.708A>G p.Q236= | Silent (SNP) | VAF 22/198 reads (11%) | catalogued as COSV60195833; called by muse, mutect2, varscan2
- FOXI1 | c.582G>T p.G194= | Silent (SNP) | VAF 32/190 reads (17%) | catalogued as COSV60389067; called by muse, mutect2, varscan2
- IFT140 | c.2001G>A p.Q667= | Silent (SNP) | VAF 40/135 reads (30%) | catalogued as COSV68490696; called by muse, mutect2, varscan2
- L3MBTL4 | c.321G>A p.A107= | Silent (SNP) | VAF 120/267 reads (45%) | catalogued as rs745852553, COSV53128281; called by muse, mutect2, varscan2
- NLRP12 | c.654G>A p.A218= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as rs745766441, COSV60749919; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OLFML2B | c.1875C>T p.D625= | Silent (SNP) | VAF 11/62 reads (18%) | catalogued as rs1379795545, COSV54195135, COSV54195746; called by muse, mutect2, varscan2
- PAX3 | c.195C>T p.H65= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs1319212514, COSV51341010, COSV99286849; called by muse, mutect2, varscan2
- RPL39 | c.31C>A p.R11= | Silent (SNP) | VAF 41/149 reads (28%) | catalogued as COSV64294255; called by muse, mutect2, varscan2
- SCN9A | c.2031G>A p.E677= (on ENST00000303354; = p.E666= on NM_002977.3) | Silent (SNP) | VAF 53/363 reads (15%) | catalogued as COSV57614846; called by muse, mutect2, varscan2
- SF1 | c.1626G>A p.P542= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as rs1376845011, COSV57116004; called by muse, mutect2, varscan2
- SLITRK1 | c.1047C>T p.H349= | Silent (SNP) | VAF 34/106 reads (32%) | catalogued as rs1330457491, COSV65676559; called by muse, mutect2, varscan2
- SNX21 | c.1029A>T p.S343= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as COSV54170241; called by muse, mutect2
- SOX21 | c.60G>A p.R20= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV100977872; called by muse, mutect2
- SPATA7 | c.1149A>G p.L383= | Silent (SNP) | VAF 52/149 reads (35%) | catalogued as COSV50418242; called by muse, varscan2
- STXBP5 | c.702C>T p.Y234= | Silent (SNP) | VAF 16/610 reads (3%) | catalogued as COSV99468866; called by muse, mutect2
- TECTA | c.2040C>T p.G680= | Silent (SNP) | VAF 12/54 reads (22%) | catalogued as COSV50735919; called by muse, mutect2, varscan2
- TLR7 | c.2217G>A p.T739= | Silent (SNP) | VAF 17/121 reads (14%) | catalogued as rs192616579, COSV66123832; called by muse, mutect2, varscan2
- TTLL6 | c.1740C>T p.A580= (on ENST00000393382 / NM_001130918.3; = p.A273= on NM_173623.3) | Silent (SNP) | VAF 111/695 reads (16%) | catalogued as rs141189437; called by muse, mutect2, varscan2
- UNC5D | c.2205G>T p.L735= | Silent (SNP) | VAF 21/175 reads (12%) | catalogued as COSV54808229; called by muse, mutect2, varscan2
- VGLL1 | c.555C>T p.A185= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as rs749163851, COSV65703496; called by muse, mutect2, varscan2
- WNK1 | c.1143G>A p.K381= | Silent (SNP) | VAF 32/277 reads (12%) | catalogued as COSV60037709; called by muse, mutect2, varscan2
- ATP2B2 | c.782-6112C>T | Intron (SNP) | VAF 27/102 reads (26%) | catalogued as rs941703617, COSV100659479; called by muse, mutect2, varscan2
- FBXW11 | c.148-3596A>G | Intron (SNP) | VAF 120/387 reads (31%) | catalogued as COSV99439615; called by muse, mutect2, varscan2
- MIR372 | n.51C>T | RNA (SNP) | VAF 43/102 reads (42%) | called by muse, mutect2, varscan2
- POLA1 | c.2947-21332G>A | Intron (SNP) | VAF 18/100 reads (18%) | catalogued as rs765642632, COSV66888053; called by muse, mutect2, varscan2
- SLITRK2 | chrX:145827829 C>T | 3'Flank (SNP) | VAF 54/198 reads (27%) | catalogued as rs370861051, COSV59426757, COSV59427427; called by muse, mutect2, varscan2
